Surgical pathology report (de-identified scan), TCGA case TCGA-HW-8319, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-8319-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Left frontal mass.

Specimens Submitted:

- 1: Left frontal lobe brain tumor [REDACTED]
2: Left frontal lobe brain tumor # 2

DIAGNOSIS:

1. Left frontal lobe brain tumor [REDACTED]
- Astrocytoma, see part 2
2. Left frontal lobe brain tumor # 2:
Part # 2
TUMOR TYPE:
Anaplastic astrocytoma
WHO GRADE:
III
Comment: Material will be forwarded for molecular studies and IDH immunostain.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	Unst_Recut	
	NEG CONT	
	IMM RECUT	
	IDH1-H09	
	RECUT	

Gross Description:

[page 2 of 2]
1. The specimen is received fresh for frozen section consultation, labeled "Left frontal lobe brain tumor (fs)" and consists of multiple, irregularly shaped, soft, tan-white fragments of tissue measuring 1.5 x 0.5 x <0.1 cm. A portion of the specimen is utilized to prepare smears. The remainder of the specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

2). The specimen is received in formalin labeled, "Left frontal lobe brain tumor #2" and consists of multiple fragmented segments of soft whitish tan convoluted brain tissue measuring 3.5 x 1.5 x 1.5 cm in aggregate. Submitted in total.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: Left frontal lobe brain tumor

Block	Sect. Site	PCs
1	FSC	1

Part 2: Left frontal lobe brain tumor # 2

Block	Sect. Site	PCs
6	u	10

Procedures/Addenda:

Addendum

Status: Signed Out

Addendum Diagnosis

2. Frontal lobe # 2, left;biopsy:

- Immunohistochemical study is positive for tumor cell expression of R132H mutant IDH1.

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Left frontal lobe brain tumor (fs): Infiltrating astrocytoma, low grade on representative section
Permanent diagnosis: same

Source: NCI Genomic Data Commons file 83ee4fd7-45e1-494f-b113-8529e9e99a9a (TCGA-HW-8319.C90E82A8-F877-40D8-B75F-F67E1714F58E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).